Somatic mutation profile of tumor specimen TCGA-S9-A6WM-01A (aliquot TCGA-S9-A6WM-01A-12D-A33T-08) from TCGA case TCGA-S9-A6WM, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 59.6 years (21,761 days).
Specimen TCGA-S9-A6WM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bae0844b-9ee7-4f26-8196-cd4f7b90abfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WM-10A (Blood Derived Normal), aliquot TCGA-S9-A6WM-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfbd19e0-f3b1-44b1-9091-a61403b76852

The open-access MAF lists 55 somatic variants for this specimen: 46 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 40, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 168/393 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs757177041, COSV100710420, COSV61263698; called by muse, mutect2, varscan2
- ADAMTS15 | c.1994C>G p.S665C | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100143381; called by muse, mutect2, varscan2
- ARMCX5 | c.1205C>A p.S402Y | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV99863295; called by muse, mutect2
- CD14 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs751158365, COSV100117547; called by muse, mutect2, varscan2
- CD22 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 145/357 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs575288611, COSV99323215; called by muse, mutect2, varscan2
- CD72 | c.629A>G p.E210G | Missense Mutation (SNP) | VAF 132/279 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99427444; called by muse, mutect2, varscan2
- CUL4B | c.1279A>T p.R427* | Nonsense Mutation (SNP) | VAF 93/202 reads (46%) | catalogued as COSV100340507; called by muse, mutect2, varscan2
- CXorf21 | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV100973278; called by mutect2, varscan2
- DSC3 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs138126171; called by muse, mutect2, varscan2
- GH2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762966262, COSV60426398, COSV60426542; called by muse, mutect2, varscan2
- GIGYF1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1019609332, COSV99309101; called by muse, mutect2, varscan2
- GPR6 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254326; called by muse, mutect2, varscan2
- GPRIN2 | c.1224G>C p.Q408H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs941211547, COSV100966385; called by muse, mutect2
- IFT172 | c.1750G>C p.G584R | Missense Mutation (SNP) | VAF 343/823 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99562481; called by muse, mutect2, varscan2
- IGHG2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 126/251 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as rs368941054; called by muse, mutect2, varscan2
- KIF13B | c.4267A>G p.I1423V | Missense Mutation (SNP) | VAF 153/244 reads (63%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101342262; called by muse, mutect2, varscan2
- KLHL6 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376100820; called by muse, mutect2, varscan2
- KRT86 | c.106T>A p.S36T | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV99524946; called by muse, mutect2, varscan2
- LPAR2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs201157972, COSV99179269; called by muse, mutect2, varscan2
- LRRFIP2 | c.1567-1G>T p.X523_splice | Splice Site (SNP) | VAF 90/177 reads (51%) | catalogued as COSV100368377; called by muse, mutect2, varscan2
- MAML1 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as rs144664410; called by muse, mutect2, varscan2
- MAP3K6 | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs778880492, COSV58871250; called by muse, mutect2, varscan2
- MCPH1 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.707); catalogued as rs373336510, COSV100765688; called by muse, mutect2, varscan2
- NEFM | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55330139; called by muse, mutect2, varscan2
- PCLO | c.14009C>G p.S4670C | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100432517; called by muse, mutect2, varscan2
- PLPPR1 | c.287A>T p.K96I | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV100883282; called by muse, mutect2, varscan2
- PMEL | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.936); catalogued as COSV100093061; called by muse, mutect2, varscan2
- RASSF9 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs750233982, COSV63435953; called by muse, mutect2, varscan2
- RIMBP2 | c.4C>T p.R2* | Nonsense Mutation (SNP) | VAF 41/85 reads (48%) | catalogued as rs138967663, COSV99900140; called by muse, mutect2, varscan2
- RNF128 | c.17G>T p.R6M | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV60949248; called by muse, mutect2
- RYR2 | c.12373G>A p.V4125I | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as rs775417996, COSV63658123, COSV63663747, COSV63724087; called by muse, mutect2, varscan2
- SEMA6A | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99145609; called by muse, mutect2, varscan2
- SERPINB8 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99729167; called by muse, mutect2, varscan2
- SH2B1 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs773558526, COSV100451056; called by muse, mutect2, varscan2
- SLC34A1 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs148272921, COSV99499590; called by muse, mutect2, varscan2
- SLITRK4 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 119/323 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as rs142699085, COSV100567349; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 283/633 reads (45%) | PolyPhen probably damaging (0.938); catalogued as COSV99336411; called by muse, mutect2, varscan2
- SYT17 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs764089204, COSV100810713; called by muse, mutect2, varscan2
- TENM1 | c.7393A>G p.K2465E | Missense Mutation (SNP) | VAF 140/384 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as COSV100950020; called by muse, mutect2, varscan2
- TIAM2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.417); catalogued as rs146734733; called by muse, mutect2, varscan2
- TLE4 | c.2048A>G p.N683S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as rs778417015, COSV99512107; called by muse, mutect2, varscan2
- TRPM3 | c.1105C>T p.R369W (on ENST00000357533 / NM_001366142.2; = p.R214W on NM_020952.6) | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1428133590, COSV62471597; called by muse, mutect2, varscan2
- TYRO3 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs756887230, COSV99777617; called by muse, mutect2, varscan2
- MYOM1 | c.1281del p.V428Lfs*40 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | called by mutect2, pindel, varscan2
- PLEKHA8 | c.401_405del p.T134Rfs*11 | Frame Shift Del (DEL) | VAF 85/417 reads (20%) | called by mutect2, pindel, varscan2
- ROR1 | c.2410G>A p.G804S | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2
- EPHX4 | c.921C>T p.D307= | Silent (SNP) | VAF 24/344 reads (7%) | catalogued as rs897937221, COSV64889439; called by muse, mutect2
- HTR4 | c.1137C>T p.D379= | Silent (SNP) | VAF 92/248 reads (37%) | catalogued as rs773888647, COSV100088052, COSV58799179; called by muse, mutect2, varscan2
- IL2 | c.441C>T p.S147= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV99900767; called by muse, mutect2, varscan2
- KRT25 | c.732C>T p.P244= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV100379923; called by muse, mutect2, varscan2
- MAGEE1 | c.516G>A p.T172= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs1210630676, COSV63910231; called by muse, mutect2, varscan2
- P2RY4 | c.711G>A p.S237= | Silent (SNP) | VAF 47/75 reads (63%) | catalogued as rs1319656295, COSV100997021; called by muse, mutect2, varscan2
- PCDHB8 | c.1386C>T p.R462= | Silent (SNP) | VAF 119/931 reads (13%) | catalogued as rs782363540, COSV99175595; called by muse, mutect2, varscan2
- TTN | c.2226C>T p.S742= (on ENST00000591111; = p.S696= on NM_003319.4) | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as rs151025677, COSV60391454; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZMYND19 | c.444G>C p.R148= | Silent (SNP) | VAF 224/552 reads (41%) | catalogued as rs1289214319, COSV99483532; called by muse, mutect2, varscan2
